Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A03J, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A03J-01A (Primary Tumor).

10D-0-3
adenocarcinoma, NOS 8140/3
Site: Sigmoid colon C18.7 hr 3/28/11

Internal Sample IC

Diagnosis/Diagnoses:

Colon (sigmoid) resection specimen with bland diverticuli, unremarkable oral and aboral resection margins and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria (G2, pT2).

A follow-up report on the lymph node status will be issued.

Follow-up report:

34 lymph nodes of up to 0.9 cm in size were dissected out from the pericolic fatty tissue in the vicinity of the tumor after clarification with acetone.

These were found to be entirely tumor-free on microscopy.

In conclusion or in summary, therefore, a stage of pT2 pN0 (0/34) is obtained.

Source: NCI Genomic Data Commons file 1891c612-6693-43d2-a484-1e236475c84c (TCGA-AA-A03J.DECA4002-D8E2-42A2-817C-BCDDA0DB5B7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).